Gene-level copy-number profile of tumor specimen TCGA-EB-A3HV-01A from TCGA case TCGA-EB-A3HV, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 37.5 years (13,712 days).
Specimen TCGA-EB-A3HV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.cd7524ab-1350-4d53-896a-6fbd250432d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A3HV-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/524a1bbd-7d8b-4021-8fb5-42a9b896985b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 11,407; copy number 2: 44,747; copy number 3: 3,448; copy number 4: 11; copy number 5: 66; copy number 6: 18; copy number 7: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A3HV-01A-11D-A219-01): tumor purity 0.75, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–26,892,803, 53 genes (within-gene range 0–1): MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 147 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:7,830,378–8,486,930, 18 genes, copy number 5: C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458.
- chr5:29,600,676–32,222,347, 41 genes, copy number 5: UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1, AC026433.1, RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1.
- chr5:32,522,758–32,888,145, 6 genes, copy number 5: AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1.
- chr5:32,947,443–32,962,467, 1 gene, copy number 5 (within-gene range 2–5): LINC02120.
- chr5:37,209,364–42,721,878, 81 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,021. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
